CCDI case PBCMKS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/061c5942-3961-41a4-9b5e-b55f790685e3

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 16.6 years (6,061 days).

Biospecimens (3 samples)
- Samples 0DVCDV, 0DVCFJ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCFU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
